CCDI case PBCDCK — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/ac7db9e9-51e8-4d22-a993-d580a3c83229

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Carcinoid tumor of uncertain malignant potential: ICD-O-3 morphology code: 8240/1; Tissue or organ of origin: Appendix; Age at diagnosis: 16.5 years (6,039 days).

Biospecimens (2 samples)
- Sample 0DP46W: Tissue type: Normal; Specimen type: Peripheral Whole Blood. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
- Sample 0DP47O: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
